Somatic mutation profile of tumor specimen MMRF_2644_1_BM_CD138pos (aliquot MMRF_2644_1_BM_CD138pos_T1_KHS5U_L13416) from MMRF case MMRF_2644, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.9 years (17,875 days).
Specimen MMRF_2644_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2cae0187-478a-4178-bce2-73519f970ae6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2644_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2644_1_PB_WBC_C3_KHS5U_L13417; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e18383de-11dd-4adb-856a-1db66fc36cd9

The open-access MAF lists 82 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 21, Intron 17, Silent 9, 5'UTR 4, Nonsense Mutation 2, 3'Flank 2, RNA 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1921A>G p.K641E (on ENST00000288602 / NM_001374244.1; = p.K601E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs121913364, CM092083, COSV56058494; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- AFF1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1192247383; called by muse, mutect2
- APOA5 | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as CM145191; called by muse, mutect2, varscan2
- AZIN1 | c.1189G>A p.D397N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV61481041; called by mutect2, varscan2
- CCDC168 | c.15256G>C p.D5086H | Missense Mutation (SNP) | VAF 23/224 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100487614; called by muse, mutect2, varscan2
- CKMT2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs748332374, COSV99562240; called by muse, mutect2, varscan2
- GLT8D2 | c.682C>G p.P228A | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1270657379, COSV99054357; called by mutect2, varscan2
- HS3ST6 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs376074247; called by muse, mutect2, varscan2
- IGKJ4 | c.31A>C p.I11L | Missense Mutation (SNP) | VAF 15/71 reads (21%) | PolyPhen benign (0.009); catalogued as rs139461207; called by muse, mutect2, varscan2
- PKN3 | c.303G>C p.Q101H | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.656); catalogued as rs748058657; called by muse, mutect2, varscan2
- RAD21 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.142); catalogued as COSV52058234; called by muse, mutect2, varscan2
- SCNN1D | c.863C>T p.T288M (on ENST00000338555; = p.T452M on NM_001130413.4) | Missense Mutation (SNP) | VAF 64/446 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139483395; called by muse, mutect2, varscan2
- TENT5A | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 45/306 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760485786; called by muse, mutect2, varscan2
- VIM | c.1349G>C p.R450T | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV56406985; called by muse, mutect2, varscan2
- ZNF800 | c.1751A>G p.H584R | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs140198904; called by muse, mutect2, varscan2
- BRCA2 | c.2722G>T p.E908* | Nonsense Mutation (SNP) | VAF 33/83 reads (40%) | called by muse, mutect2, varscan2
- CACNA1I | c.2407A>G p.N803D | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CLASP2 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- CNGB3 | c.1689C>G p.I563M | Missense Mutation (SNP) | VAF 45/365 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CYTIP | c.542T>G p.L181* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- ENOSF1 | c.665G>A p.G222D (on ENST00000340116 / NM_001354066.2; = p.G174D on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- PITX2 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); called by muse, mutect2
- TECRL | c.239C>A p.T80K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.025); called by muse, mutect2
- TMCC1 | c.592G>T p.V198L | Missense Mutation (SNP) | VAF 75/663 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZDBF2 | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.021); called by muse, mutect2
- ZNF462 | c.6711G>A p.M2237I | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- DUSP2 | c.378C>T p.Y126= | Silent (SNP) | VAF 91/205 reads (44%) | catalogued as COSV56619695; called by muse, mutect2, varscan2
- IGKV2-30 | c.303C>T p.S101= | Silent (SNP) | VAF 38/155 reads (25%) | called by muse, mutect2
- KIF7 | c.1191C>T p.A397= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1200917536; called by muse, mutect2, varscan2
- LGSN | c.1426C>T p.L476= | Silent (SNP) | VAF 93/220 reads (42%) | catalogued as rs768036882, COSV101040200; called by muse, mutect2, varscan2
- LHX9 | c.315C>G p.L105= | Silent (SNP) | VAF 13/468 reads (3%) | catalogued as COSV100435559; called by muse, mutect2
- PSMA8 | c.357A>T p.I119= | Silent (SNP) | VAF 36/82 reads (44%) | called by muse, mutect2, varscan2
- RYR2 | c.2871T>A p.A957= | Silent (SNP) | VAF 66/150 reads (44%) | called by muse, mutect2, varscan2
- SLC17A8 | c.852G>A p.K284= | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as COSV60123090; called by muse, mutect2
- TSC2 | c.297C>T p.H99= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs752498350; ClinVar: likely benign / benign; called by muse, mutect2, varscan2
- AGAP1 | c.1646-21751C>T | Intron (SNP) | VAF 37/113 reads (33%) | catalogued as rs1339144803; called by muse, mutect2, varscan2
- APTX | c.874+18G>T | Intron (SNP) | VAF 19/37 reads (51%) | catalogued as rs758751674; called by muse, mutect2, varscan2
- ARHGAP29 | c.1282-47A>C | Intron (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- ASPH | c.322+5536G>T | Intron (SNP) | VAF 52/118 reads (44%) | called by muse, mutect2, varscan2
- BACE1 | c.-150G>A | 5'UTR (SNP) | VAF 17/60 reads (28%) | catalogued as COSV57286650; called by muse, mutect2, varscan2
- CACNG3 | c.-23C>T | 5'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- CBLB | c.*1577A>T | 3'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- CCDC141 | c.4325+728A>T | Intron (SNP) | VAF 12/129 reads (9%) | called by muse, mutect2
- CLEC16A | c.*3488A>G | 3'UTR (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- CLTC | c.*1588G>C | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- CRISP3 | chr6:49728385 G>A | 3'Flank (SNP) | VAF 8/71 reads (11%) | called by mutect2, varscan2
- DNAH14 | c.1415+554G>T | Intron (SNP) | VAF 35/99 reads (35%) | called by muse, mutect2, varscan2
- F2RL2 | c.*1372T>G | 3'UTR (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- GABRB3 | chr15:26773700 G>A | 5'Flank (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- GLT8D2 | c.767+17C>T | Intron (SNP) | VAF 7/38 reads (18%) | called by mutect2, varscan2
- GNAQ | c.*2513G>T | 3'UTR (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- HSPB7 | c.*1399C>T | 3'UTR (SNP) | VAF 20/293 reads (7%) | called by muse, mutect2
- KCNA6 | c.*13G>A | 3'UTR (SNP) | VAF 59/152 reads (39%) | called by muse, varscan2
- KRTAP4-9 | c.*276C>A | 3'UTR (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- LHCGR | c.*53del | 3'UTR (DEL) | VAF 39/104 reads (38%) | catalogued as rs200887026; called by mutect2, varscan2
- LRIT3 | c.*817T>G | 3'UTR (SNP) | VAF 46/127 reads (36%) | called by muse, mutect2, varscan2
- MTMR7 | c.1620+47G>A | Intron (SNP) | VAF 38/80 reads (48%) | catalogued as rs1202707609; called by muse, mutect2, varscan2
- MUSK | c.-49C>T | 5'UTR (SNP) | VAF 85/524 reads (16%) | catalogued as rs1245918162, COSV99504636; called by muse, mutect2, varscan2
- OPRK1 | c.*3229G>T | 3'UTR (SNP) | VAF 28/90 reads (31%) | called by muse, mutect2, varscan2
- OR4Q3 | c.*38T>A | 3'UTR (SNP) | VAF 28/268 reads (10%) | called by muse, mutect2, varscan2
- PCDH15 | c.*978A>G | 3'UTR (SNP) | VAF 41/78 reads (53%) | catalogued as rs1347084014; called by muse, mutect2, varscan2
- PEG10 | c.*4336T>C | 3'UTR (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- PLA2G4C | c.763+19G>T | Intron (SNP) | VAF 30/488 reads (6%) | called by muse, mutect2
- POM121L4P | n.1387C>T | RNA (SNP) | VAF 41/126 reads (33%) | catalogued as rs766662085; called by muse, mutect2, varscan2
- PPARGC1B | c.*4862A>C | 3'UTR (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- PPARGC1B | c.*4863C>A | 3'UTR (SNP) | VAF 12/172 reads (7%) | called by muse, mutect2
- PRELID3A | c.33-19G>A | Intron (SNP) | VAF 74/173 reads (43%) | catalogued as rs370050988; called by muse, mutect2, varscan2
- PTEN | c.-366_-363del | 5'UTR (DEL) | VAF 4/24 reads (17%) | catalogued as rs1365232630; called by mutect2, pindel
- RABGAP1L | c.1711-89163A>G | Intron (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- RBM5 | c.1278+60A>G | Intron (SNP) | VAF 29/84 reads (35%) | catalogued as rs1158431696; called by muse, mutect2, varscan2
- RNF144B | c.*1301C>G | 3'UTR (SNP) | VAF 8/125 reads (6%) | called by muse, mutect2
- SHANK2 | c.1108-56219G>T | Intron (SNP) | VAF 26/180 reads (14%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.1307C>T | RNA (SNP) | VAF 28/68 reads (41%) | catalogued as rs532792828; called by muse, mutect2, varscan2
- TET1 | c.*2183A>G | 3'UTR (SNP) | VAF 15/142 reads (11%) | called by muse, mutect2, varscan2
- THEM4 | c.286+142G>A | Intron (SNP) | VAF 37/90 reads (41%) | called by muse, mutect2, varscan2
- TTC21B | c.*1072A>T | 3'UTR (SNP) | VAF 35/78 reads (45%) | called by muse, mutect2, varscan2
- UBE3A | c.29+1477T>A | Intron (SNP) | VAF 76/163 reads (47%) | called by muse, mutect2, varscan2
- VSIG8 | c.*210G>T | 3'UTR (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- XKR6 | c.764+5735G>A | Intron (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- ZDHHC14 | c.*957dup | 3'UTR (INS) | VAF 19/60 reads (32%) | called by mutect2, varscan2
- ZNF583 | chr19:56427192 A>T | 3'Flank (SNP) | VAF 24/122 reads (20%) | called by muse, mutect2, varscan2
- ZNF813 | c.142+1515T>A | Intron (SNP) | VAF 29/42 reads (69%) | catalogued as rs1172048928; called by muse, mutect2, varscan2
